CCDI case PBBTFP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/5f6ccc91-ff7b-4712-8294-66cbf7861179

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 6.2 years (2,256 days).

Biospecimens (3 samples)
- Sample 0DGIIL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGIIM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGIIN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
